Somatic mutation profile of tumor specimen BA2387D (aliquot aq-BA2387D) from BEATAML1.0 case 2454, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute monoblastic and monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.8 years (26,218 days).
Specimen BA2387D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2538f97-2687-42d7-a0e9-e7719937ad6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2581D (Solid Tissue Normal), aliquot aq-BA2581D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c5b2493-3ad7-47ef-9512-7ce178ce7fb9

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 19/141 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by muse, varscan2
- PPP4C | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV54222859; called by muse, mutect2, varscan2
- SVOPL | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55995702; called by muse, mutect2
- SYT3 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV58895472; called by muse, mutect2
- WFIKKN1 | c.375C>A p.S125R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV50194965; called by muse, mutect2
- CDK6 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.131); called by muse, mutect2
- CILP | c.3139G>T p.V1047F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2
- DUS1L | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.405); called by muse, mutect2
- USP47 | c.1156C>A p.L386M (on ENST00000399455 / NM_001372095.1; = p.L298M on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- C6orf47 | c.546G>T p.L182= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- SIX5 | c.1128G>T p.G376= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs982049198; called by muse, mutect2
- SLC13A1 | c.129G>T p.V43= | Silent (SNP) | VAF 58/62 reads (94%) | catalogued as rs1349520213; called by mutect2, varscan2
- USP7 | c.1701G>T p.V567= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- ZSWIM8 | c.*176C>A | 3'UTR (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
